Somatic mutation profile of tumor specimen C3L-02651-04 (aliquot CPT0241980007) from CPTAC case C3L-02651, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 81.5 years (29,752 days).
Specimen C3L-02651-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b570fc87-75aa-442c-8c93-be3e94289e21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02651-32 (Blood Derived Normal), aliquot CPT0242110002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8174700e-67ba-4d23-89c9-2991f611d2e5

The open-access MAF lists 476 somatic variants for this specimen: 336 protein-altering or splice-affecting, 83 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 293, Silent 83, Intron 25, Nonsense Mutation 18, Frame Shift Del 13, 5'UTR 12, RNA 7, 5'Flank 6, 3'Flank 5, Splice Site 5, Splice Region 4, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 45/315 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs104894230, CM053284, CM081305, CM123157, COSV54236734, COSV54236774, COSV54238174; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.711G>C p.M237I | Missense Mutation (SNP) | VAF 71/438 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587782664, CM011014, COSV52661887, COSV52681050, COSV52751406; called by muse, mutect2, varscan2
- ABCB9 | c.1291G>T p.G431W | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54890347; called by muse, mutect2, varscan2
- ADGRL4 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as rs751414077; called by muse, mutect2
- AFF2 | c.1540C>G p.R514G | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs782804418; called by muse, mutect2, varscan2
- ANKRD30B | c.470C>T p.T157I | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs780368020; called by muse, mutect2
- APOB | c.9224C>A p.A3075E | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as rs766426430; called by muse, mutect2, varscan2
- AQP12A | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 81/549 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774372497, COSV61836788; called by muse, mutect2, varscan2
- BAAT | c.804G>T p.Q268H | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV52287958; called by muse, mutect2, varscan2
- BMP10 | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.224); catalogued as rs1033032932; called by muse, mutect2, varscan2
- CACNA1H | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs58593315; called by muse, mutect2, varscan2
- CATSPER2 | c.842+1G>T p.X281_splice | Splice Site (SNP) | VAF 56/226 reads (25%) | catalogued as COSV58660954, COSV58661550; called by muse, mutect2, varscan2
- CBR4 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 10/222 reads (5%) | catalogued as COSV100085758, COSV60370400; called by muse, mutect2
- CCDC171 | c.3436C>T p.H1146Y | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.754); catalogued as rs764483491; called by muse, mutect2, varscan2
- CCDC180 | c.4307G>T p.R1436L | Missense Mutation (SNP) | VAF 75/229 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); catalogued as COSV100826609; called by muse, mutect2, varscan2
- CCT8L2 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63464109; called by muse, mutect2
- CD38 | c.632C>A p.S211Y | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432068695; called by muse, mutect2, varscan2
- CLIC6 | c.1942C>A p.H648N (on ENST00000360731 / NM_001317009.2; = p.H630N on NM_053277.3) | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV62448597; called by muse, mutect2, varscan2
- CMYA5 | c.10896G>A p.M3632I | Missense Mutation (SNP) | VAF 43/322 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.24); catalogued as COSV71406638; called by muse, mutect2, varscan2
- CNOT1 | c.2827C>T p.R943C | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV55313860; called by muse, mutect2, varscan2
- COL11A1 | c.4773G>T p.E1591D | Missense Mutation (SNP) | VAF 30/257 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV62175942; called by muse, mutect2, varscan2
- CSMD1 | c.4928C>A p.P1643H (on ENST00000520002; = p.P1642H on NM_033225.6) | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100151034, COSV59346671; called by muse, mutect2
- DCHS1 | c.6649C>T p.R2217C | Missense Mutation (SNP) | VAF 39/363 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as rs768742298, COSV55038114; called by muse, mutect2, varscan2
- DCHS2 | c.58G>C p.G20R | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.238); catalogued as rs943632699; called by muse, mutect2
- EFCAB6 | c.2485G>A p.D829N | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99034693; called by muse, mutect2
- ENTPD2 | c.1245C>A p.F415L (on ENST00000355097 / NM_203468.3; = p.F392L on NM_001246.4) | Missense Mutation (SNP) | VAF 47/339 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773875166; called by muse, varscan2
- EPB41 | c.*5A>T | Splice Region (SNP) | VAF 45/382 reads (12%) | catalogued as COSV100548842; called by muse, mutect2, varscan2
- FAM47A | c.1573C>A p.R525S | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.858); catalogued as COSV60494397; called by muse, varscan2
- FAM86DP | n.514G>T | Splice Region (SNP) | VAF 69/388 reads (18%) | catalogued as rs774135314; called by muse, mutect2, varscan2
- FER1L6 | c.3971C>A p.S1324Y | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV67552121; called by muse, mutect2, varscan2
- FGF10 | c.532G>T p.V178L | Missense Mutation (SNP) | VAF 35/357 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.265); catalogued as COSV99240801; called by muse, mutect2, varscan2
- FN1 | c.5041G>A p.D1681N | Missense Mutation (SNP) | VAF 85/530 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV60563915; called by muse, mutect2, varscan2
- FOXR2 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV59259454, COSV59259611; called by muse, mutect2, varscan2
- FYCO1 | c.4205G>T p.S1402I | Missense Mutation (SNP) | VAF 79/505 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV56116523; called by muse, mutect2, varscan2
- GAD1 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 33/326 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as rs527691350; called by muse, mutect2, varscan2
- GKN1 | c.242G>A p.C81Y | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1354465279; called by muse, mutect2, varscan2
- GPER1 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.849); catalogued as rs1182360006, COSV99867451; called by muse, mutect2, varscan2
- GRIN3A | c.1045C>A p.P349T | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV62456003; called by muse, mutect2, varscan2
- GRK2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 36/268 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as rs771530727, COSV57952794; called by muse, mutect2, varscan2
- GRSF1 | c.1040C>G p.A347G | Missense Mutation (SNP) | VAF 28/242 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV99635423; called by muse, mutect2, varscan2
- GSE1 | c.335del p.P112Lfs*13 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs949717861; called by mutect2, varscan2
- HEPACAM2 | c.155C>G p.P52R (on ENST00000394468 / NM_001039372.4; = p.P40R on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/403 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV59058447; called by muse, mutect2, varscan2
- HMGCR | c.924G>C p.W308C | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as rs1034058316; called by muse, mutect2
- HS3ST3A1 | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.303); catalogued as rs750849331; called by mutect2, varscan2
- ITGAV | c.2980G>T p.V994L | Missense Mutation (SNP) | VAF 44/371 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1301994276; called by muse, mutect2, varscan2
- KIAA1109 | c.2383G>A p.G795S | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1363565797; called by muse, mutect2, varscan2
- KLHL34 | c.1469C>T p.A490V | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.207); catalogued as COSV65278709; called by muse, mutect2, varscan2
- KLHL38 | c.802C>A p.P268T | Missense Mutation (SNP) | VAF 58/536 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100384742; called by muse, mutect2, varscan2
- KMT2D | c.9142G>T p.D3048Y | Missense Mutation (SNP) | VAF 91/627 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99986125; called by muse, mutect2, varscan2
- LEO1 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 13/159 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV55175613; called by muse, mutect2
- LRFN1 | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.463); catalogued as COSV50505232; called by muse, mutect2, varscan2
- LRRC32 | c.1673G>A p.G558D | Missense Mutation (SNP) | VAF 65/395 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1199077993; called by muse, mutect2, varscan2
- LY6D | c.376C>G p.P126A | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.098); catalogued as COSV56661409, COSV56661575; called by muse, mutect2, varscan2
- LYST | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV67713588; called by muse, mutect2, varscan2
- MUC16 | c.33275C>A p.P11092H | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.937); catalogued as COSV67480153; called by muse, mutect2, varscan2
- MYBPC2 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 16/135 reads (12%) | catalogued as COSV100731522; called by muse, mutect2, varscan2
- NAV1 | c.1781C>T p.S594L | Missense Mutation (SNP) | VAF 32/223 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422341119, COSV55215595; called by muse, mutect2, varscan2
- NFS1 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 17/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60764132; called by muse, mutect2, varscan2
- NIN | c.3410G>A p.G1137D | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs747801398; called by muse, mutect2, varscan2
- NLRP8 | c.2461C>G p.L821V | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52588550; called by muse, mutect2
- NMT1 | c.1266C>G p.F422L | Missense Mutation (SNP) | VAF 51/365 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.632); catalogued as COSV99364865; called by muse, mutect2, varscan2
- NOP16 | c.64C>A p.L22M | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.199); catalogued as COSV99220810; called by muse, mutect2, varscan2
- NOTCH1 | c.1309G>T p.E437* | Nonsense Mutation (SNP) | VAF 121/400 reads (30%) | catalogued as rs1060502238; called by muse, mutect2, varscan2
- NPHS2 | c.560T>A p.M187K | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as CD087864; called by muse, mutect2
- OR2AJ1 | c.896C>A p.A299E | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1434343802, COSV59088877; called by muse, mutect2
- OR2D3 | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 25/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53491906; called by muse, mutect2
- OR3A1 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs1288025099; called by muse, mutect2, varscan2
- OR4C46 | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.32); catalogued as rs372915515; called by muse, mutect2
- OR4K5 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 36/500 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs567087443, COSV100262396, COSV60003289; called by muse, mutect2
- OR4Q3 | c.401C>G p.A134G | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59179645; called by muse, mutect2, varscan2
- PCDHA12 | c.1931G>C p.R644P | Missense Mutation (SNP) | VAF 61/537 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as rs199806507, COSV99166148; called by muse, mutect2, varscan2
- PIP | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV52120257; called by muse, mutect2
- PKD2L2 | c.557C>G p.P186R | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV51797082; called by muse, mutect2
- PPHLN1 | c.751G>C p.E251Q | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.678); catalogued as COSV56732811; called by muse, mutect2, varscan2
- PPIL4 | c.569G>T p.R190L | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs761940773, COSV53568668; called by muse, mutect2, varscan2
- PRUNE2 | c.3878T>A p.L1293Q | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV100944773; called by muse, mutect2, varscan2
- REG1A | c.344G>T p.S115I | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV99286757; called by muse, mutect2, varscan2
- RFPL2 | c.114C>A p.S38R | Missense Mutation (SNP) | VAF 25/171 reads (15%) | PolyPhen benign (0.307); catalogued as COSV50720992; called by muse, mutect2, varscan2
- RUBCNL | c.1456G>T p.V486F | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59792449; called by muse, mutect2, varscan2
- RUFY4 | c.316C>A p.R106S | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs964068397, COSV60249775; called by muse, mutect2
- RYR2 | c.10159G>T p.E3387* | Nonsense Mutation (SNP) | VAF 44/220 reads (20%) | catalogued as COSV63668197, COSV63712965; called by muse, varscan2
- SDS | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs142532688; called by muse, mutect2
- SEMA5A | c.2635del p.I879Sfs*80 | Frame Shift Del (DEL) | VAF 50/277 reads (18%) | catalogued as COSV66783897; called by mutect2, pindel, varscan2
- SEMA5B | c.2599C>T p.R867W | Missense Mutation (SNP) | VAF 26/244 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1164164320, COSV52095872, COSV99533692; called by muse, mutect2, varscan2
- SHANK1 | c.2372C>G p.S791* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as COSV53241844; called by muse, mutect2, varscan2
- SHANK1 | c.2134T>C p.W712R | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs1459453126; called by muse, mutect2, varscan2
- SLC28A3 | c.1449+2T>A p.X483_splice | Splice Site (SNP) | VAF 27/91 reads (30%) | catalogued as COSV100883334; called by muse, varscan2
- SLC35F4 | c.1176G>T p.W392C (on ENST00000339762 / NM_001352015.2; = p.W356C on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV60267304; called by muse, mutect2, varscan2
- SLC41A3 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59987706; called by muse, mutect2, varscan2
- SLIT3 | c.3974C>T p.S1325F | Missense Mutation (SNP) | VAF 78/608 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV60605450; called by muse, mutect2, varscan2
- SOX6 | c.1141C>T p.P381S (on ENST00000528429 / NM_001145819.2; = p.P340S on NM_017508.3) | Missense Mutation (SNP) | VAF 66/388 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs372492993; called by muse, mutect2, varscan2
- SRPX2 | c.74G>A p.W25* | Nonsense Mutation (SNP) | VAF 37/237 reads (16%) | catalogued as rs868428466; called by muse, mutect2, varscan2
- STRA6 | c.1917G>C p.W639C | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51434809; called by muse, mutect2
- TBC1D15 | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1178723060; called by muse, mutect2, varscan2
- TBL3 | c.2305C>G p.Q769E | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs890174656; called by muse, mutect2, varscan2
- TBX20 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 114/407 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.145); catalogued as rs142399794; called by muse, varscan2
- TCTN2 | c.1274A>G p.Y425C | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.792); catalogued as rs1304326508; called by muse, mutect2, varscan2
- TEX15 | c.5668G>C p.D1890H (on ENST00000256246; = p.D2273H on NM_001350162.2) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99821040; called by muse, mutect2, varscan2
- TIGAR | c.606G>A p.M202I | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99463841; called by muse, mutect2, varscan2
- TNNI3K | c.2210G>T p.S737I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99630792; called by muse, mutect2, varscan2
- TOP3A | c.1315C>T p.R439C | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1238198584; called by muse, mutect2
- TRIM50 | c.1309C>G p.R437G | Missense Mutation (SNP) | VAF 55/319 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.069); catalogued as COSV53093233; called by muse, mutect2, varscan2
- UGT2B10 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV55323357; called by muse, mutect2, varscan2
- USP8 | c.937A>T p.T313S | Missense Mutation (SNP) | VAF 32/248 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.043); catalogued as rs1566873330; called by muse, mutect2, varscan2
- ZHX2 | c.2355C>G p.N785K | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV58711951; called by muse, mutect2, varscan2
- ZNF233 | c.388A>G p.R130G | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV61934020; called by muse, mutect2, varscan2
- ZNF483 | c.104G>C p.G35A | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.142); catalogued as COSV100493043; called by muse, mutect2, varscan2
- ZNF579 | c.72_95del p.R28_G35del | In Frame Del (DEL) | VAF 32/261 reads (12%) | catalogued as rs765139510; called by mutect2, varscan2
- ZNF668 | c.901G>T p.A301S | Missense Mutation (SNP) | VAF 78/449 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); catalogued as rs758444889; called by muse, mutect2, varscan2
- ZNF700 | c.221A>G p.Y74C | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as rs377132952; called by muse, mutect2, varscan2
- ZNF835 | c.1102G>A p.G368S | Missense Mutation (SNP) | VAF 37/319 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs999116627, COSV73379690; called by muse, mutect2, varscan2
- AAMP | c.1205A>G p.E402G | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ABCC11 | c.2057T>A p.V686D | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, varscan2
- ACRBP | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACTL7B | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTR10 | c.953G>A p.R318K | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2
- ACTRT2 | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 62/451 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ADAM12 | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 73/257 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM2 | c.1486T>A p.C496S | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS14 | c.1873T>G p.Y625D | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2
- ADGRF5 | c.140T>A p.L47Q | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADGRV1 | c.727G>C p.A243P | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ADORA3 | c.305T>A p.L102Q | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHCTF1 | c.6038G>T p.R2013I (on ENST00000366508; = p.R1987I on NM_015446.5) | Missense Mutation (SNP) | VAF 8/189 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); called by muse, mutect2
- AJUBA | c.1033A>T p.I345F | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- ALPG | c.1213A>G p.K405E | Missense Mutation (SNP) | VAF 46/545 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); called by muse, mutect2
- AMH | c.1301T>G p.L434R | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ANKRD1 | c.281A>C p.K94T | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ANO5 | c.684A>G p.I228M | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AP3B2 | c.2291G>A p.S764N | Missense Mutation (SNP) | VAF 48/361 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- APC | c.5008G>C p.A1670P | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- APCS | c.14T>G p.L5R | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- ARSA | c.1516G>A p.D506N | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- ARSL | c.16C>T p.H6Y | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARVCF | c.2543G>T p.R848L | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ASB11 | c.186C>A p.C62* | Nonsense Mutation (SNP) | VAF 35/135 reads (26%) | called by muse, mutect2, varscan2
- ATOH8 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ATP13A2 | c.2983G>T p.A995S | Missense Mutation (SNP) | VAF 89/642 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP13A5 | c.518G>C p.S173T | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- ATP6V1H | c.638A>G p.E213G | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- ATR | c.735A>C p.K245N | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- BEST3 | c.415A>C p.I139L | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- BICRA | c.1585G>T p.V529L | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BNIP1 | c.449C>G p.A150G | Missense Mutation (SNP) | VAF 23/288 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2
- BOD1L2 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- BRCA2 | c.681+2T>C p.X227_splice | Splice Site (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2
- BTAF1 | c.3875A>G p.D1292G | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BUB1 | c.1172A>T p.Q391L | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CABIN1 | c.698C>G p.T233R | Missense Mutation (SNP) | VAF 62/560 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CACNA1B | c.2641G>T p.A881S | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1F | c.4954G>T p.E1652* | Nonsense Mutation (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- CARS1 | c.1208C>G p.A403G | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- CBY3 | c.183C>G p.F61L | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.302); called by muse, mutect2
- CCDC169 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.172); called by muse, mutect2
- CCSER1 | c.289C>T p.H97Y | Missense Mutation (SNP) | VAF 22/189 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- CEBPZ | c.3088A>G p.S1030G | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); called by muse, mutect2
- CELF6 | c.1329T>G p.S443R | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CFAP100 | c.1276C>T p.Q426* | Nonsense Mutation (SNP) | VAF 26/160 reads (16%) | called by muse, mutect2, varscan2
- CFAP53 | c.32G>C p.R11P | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP54 | c.4507T>A p.C1503S | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC2A | c.440C>A p.A147D | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- CLK1 | c.739A>C p.S247R | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTN3 | c.2710A>G p.S904G | Missense Mutation (SNP) | VAF 24/141 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CNTN5 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNTNAP2 | c.1924C>G p.H642D | Missense Mutation (SNP) | VAF 60/425 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- COL1A2 | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 72/749 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRACR2A | c.440A>T p.E147V | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2
- CSMD3 | c.10100T>A p.F3367Y (on ENST00000297405 / NM_001363185.1; = p.F3198Y on NM_052900.3) | Missense Mutation (SNP) | VAF 38/426 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- CTNNA2 | c.1446G>C p.M482I | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CUBN | c.8455C>T p.P2819S | Missense Mutation (SNP) | VAF 36/335 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DDR1 | c.1800_1801delinsT p.R602Efs*51 (on ENST00000324771; = p.R565Efs*51 on NM_001954.4) | Frame Shift Del (DEL) | VAF 10/62 reads (16%) | called by pindel, varscan2*
- DDX11 | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 75/600 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- DDX25 | c.1111del p.E371Sfs*2 | Frame Shift Del (DEL) | VAF 26/191 reads (14%) | called by mutect2, pindel, varscan2
- DENND4A | c.5266G>C p.D1756H | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- DNAH11 | c.3029C>A p.A1010E | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.197); called by muse, varscan2
- DNAH5 | c.11201C>T p.T3734I | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2
- DPPA4 | c.359G>C p.R120P | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- DRG2 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSEL | c.2459C>G p.A820G | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.357); called by muse, mutect2
- DTD1 | c.215A>C p.Y72S | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- DTWD1 | c.679G>T p.V227F | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ECEL1 | c.1054_1055delinsG p.P352Afs*9 | Frame Shift Del (DEL) | VAF 42/334 reads (13%) | called by pindel, varscan2*
- EFCAB6 | c.2486A>T p.D829V | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2
- ELOVL6 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2
- ERBIN | c.1103A>G p.Q368R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2
- EZH1 | c.1843C>G p.L615V | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- F8 | c.4441C>G p.L1481V | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM186A | c.998C>A p.S333Y | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- FAT2 | c.6982A>T p.T2328S | Missense Mutation (SNP) | VAF 56/339 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- FBXO34 | c.1481A>G p.Y494C | Missense Mutation (SNP) | VAF 109/401 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- FER | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- FER1L5 | c.2442del p.M815* (on ENST00000623019; = p.M820* on NM_001293083.2) | Frame Shift Del (DEL) | VAF 26/201 reads (13%) | called by mutect2, pindel, varscan2
- FGA | c.2159G>T p.R720M | Missense Mutation (SNP) | VAF 35/329 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- FLI1 | c.161A>T p.Q54L | Missense Mutation (SNP) | VAF 40/315 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- FSCN2 | c.1478G>T p.*493Lext*? | Nonstop Mutation (SNP) | VAF 40/225 reads (18%) | called by muse, mutect2, varscan2
- GAB4 | c.970G>A p.G324R | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- GABRB1 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GARNL3 | c.2384C>G p.S795C | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- GDF2 | c.37C>A p.L13M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); called by mutect2, varscan2
- GDPD2 | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GKAP1 | c.841-1G>T p.X281_splice | Splice Site (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- GOLGB1 | c.5706A>T p.Q1902H | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- GRM3 | c.1706A>T p.Y569F | Missense Mutation (SNP) | VAF 35/233 reads (15%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GTPBP3 | c.835C>G p.P279A | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- H2BC7 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 127/570 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- HCRTR1 | c.703T>A p.Y235N | Missense Mutation (SNP) | VAF 59/338 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- HCST | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 38/284 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- HEPH | c.225G>T p.K75N (on ENST00000343002; = p.K129N on NM_138737.5) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HGH1 | c.693C>T p.H231= | Splice Region (SNP) | VAF 40/336 reads (12%) | called by muse, mutect2, varscan2
- HOXD3 | c.1072G>T p.V358L | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); called by muse, mutect2
- HPS3 | c.510C>G p.F170L | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HS3ST3A1 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 26/413 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); called by muse, varscan2
- HSPA13 | c.1027A>G p.S343G | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHM | c.1249C>A p.H417N | Missense Mutation (SNP) | VAF 185/657 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- IGSF11 | c.965G>T p.W322L (on ENST00000393775 / NM_001015887.3; = p.W321L on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2
- IK | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2
- IMPG1 | c.702G>C p.Q234H | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- INSYN2B | c.992C>A p.S331* | Nonsense Mutation (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- IQUB | c.214G>T p.E72* | Nonsense Mutation (SNP) | VAF 13/116 reads (11%) | called by muse, mutect2, varscan2
- KBTBD12 | c.135del p.H45Qfs*42 | Frame Shift Del (DEL) | VAF 28/237 reads (12%) | called by mutect2, pindel, varscan2
- KIAA1549 | c.3935T>C p.V1312A | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL2 | c.428_430del p.K143del | In Frame Del (DEL) | VAF 26/216 reads (12%) | called by pindel, varscan2
- KNTC1 | c.1504G>C p.D502H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, varscan2
- KRTAP5-10 | c.392del p.K131Rfs*86 | Frame Shift Del (DEL) | VAF 49/332 reads (15%) | called by mutect2, pindel, varscan2
- LAMA1 | c.6637G>T p.G2213C | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LAMA3 | c.5869G>C p.E1957Q (on ENST00000313654 / NM_198129.4; = p.E348Q on NM_000227.6) | Missense Mutation (SNP) | VAF 49/396 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- LAMTOR4 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- LANCL3 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- LCOR | c.3176C>A p.S1059* | Nonsense Mutation (SNP) | VAF 45/233 reads (19%) | called by muse, mutect2, varscan2
- LEF1 | c.137A>T p.E46V | Missense Mutation (SNP) | VAF 32/303 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- LPCAT4 | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 9/212 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- MAGEB6B | c.974A>T p.Y325F | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- MALRD1 | c.6431C>T p.T2144I | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- MAP1A | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAP1B | c.7043C>G p.S2348C | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- MAP4K2 | c.1815del p.N606Tfs*32 | Frame Shift Del (DEL) | VAF 26/224 reads (12%) | called by mutect2, pindel, varscan2
- MARF1 | c.3022G>T p.A1008S | Missense Mutation (SNP) | VAF 17/172 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MBTPS2 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MDGA2 | c.2848G>A p.A950T (on ENST00000399232 / NM_001113498.2; = p.A652T on NM_182830.4) | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- MIEF1 | c.1098C>G p.I366M | Missense Mutation (SNP) | VAF 63/535 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- MMP17 | c.881A>T p.Y294F | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MOAP1 | c.97G>C p.A33P | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MTERF2 | c.1032A>G p.I344M | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- MTMR7 | c.413G>C p.R138P | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MUC5B | c.4986C>A p.Y1662* | Nonsense Mutation (SNP) | VAF 38/158 reads (24%) | called by muse, mutect2, varscan2
- NBPF9 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 97/779 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- NCAM2 | c.958C>A p.L320I | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- NCAPD2 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 37/277 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- NCDN | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- NEU4 | c.134G>T p.S45I (on ENST00000391969 / NM_001167602.3; = p.S57I on NM_080741.4) | Missense Mutation (SNP) | VAF 50/285 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- NEUROG3 | c.258G>C p.K86N | Missense Mutation (SNP) | VAF 153/566 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- NOP2 | c.1712C>G p.P571R (on ENST00000322166 / NM_001258308.2; = p.P567R on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/461 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOP9 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 56/318 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NPAP1 | c.2525C>A p.S842Y | Missense Mutation (SNP) | VAF 52/294 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- NPHS1 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 45/320 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- NPY5R | c.997G>T p.V333F | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- NRXN3 | c.2593C>A p.L865M (on ENST00000335750 / NM_001330195.2; = p.L492M on NM_004796.6) | Missense Mutation (SNP) | VAF 88/278 reads (32%) | SIFT tolerated (0.6); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- OLR1 | c.158T>C p.I53T | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10A7 | c.120G>T p.L40F | Missense Mutation (SNP) | VAF 45/502 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.017); called by muse, mutect2
- OR9G1 | c.229A>T p.T77S | Missense Mutation (SNP) | VAF 22/458 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2
- P2RX1 | c.1066A>G p.I356V | Missense Mutation (SNP) | VAF 43/360 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PASK | c.2057_2058del p.E686Vfs*49 | Frame Shift Del (DEL) | VAF 19/126 reads (15%) | called by pindel, varscan2
- PCDHGA1 | c.1593A>T p.K531N | Missense Mutation (SNP) | VAF 55/364 reads (15%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PDE11A | c.380G>C p.R127P | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PDE4DIP | c.5738G>T p.R1913I | Missense Mutation (SNP) | VAF 22/158 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- PDILT | c.1173G>T p.Q391H | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.898); called by muse, mutect2
- PEX5L | c.1148T>A p.L383H | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHF21B | c.434G>T p.S145I | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- PITPNM1 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEC | c.12884A>T p.Y4295F (on ENST00000322810 / NM_201380.4; = p.Y4185F on NM_000445.5) | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLET1 | c.244A>T p.S82C | Missense Mutation (SNP) | VAF 91/546 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- PLXNA3 | c.515A>T p.D172V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.394); called by muse, varscan2
- POLDIP3 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- POP4 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PPP1R7 | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 16/177 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRR33 | c.1294C>A p.R432S | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- PSKH2 | c.486G>T p.R162S | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PSMD3 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 44/328 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- RETSAT | c.810del p.N271Tfs*16 | Frame Shift Del (DEL) | VAF 37/301 reads (12%) | called by mutect2, pindel, varscan2
- RTL1 | c.1598A>T p.N533I | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- SCN3A | c.3971T>C p.V1324A | Missense Mutation (SNP) | VAF 49/399 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCN7A | c.4240G>T p.V1414L | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SCNN1G | c.491A>T p.D164V | Missense Mutation (SNP) | VAF 74/589 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SCTR | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 41/359 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SCUBE1 | c.2875T>A p.Y959N | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEC14L6 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETD1B | c.1996G>C p.A666P | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.208); called by muse, mutect2
- SLC22A9 | c.98T>G p.L33R | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC24A1 | c.2395G>C p.E799Q | Missense Mutation (SNP) | VAF 35/288 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC27A3 | c.1914_1938del p.K639Lfs*49 (on ENST00000271857; = p.K511Lfs*49 on NM_024330.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 72/644 reads (11%) | called by mutect2, pindel
- SLC5A4 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC6A18 | c.750C>A p.N250K | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- SNTG1 | c.321+1G>C p.X107_splice | Splice Site (SNP) | VAF 18/209 reads (9%) | called by muse, mutect2
- SOGA1 | c.4220G>T p.R1407L | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATA31A1 | c.287A>T p.D96V | Missense Mutation (SNP) | VAF 34/393 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.399); called by muse, mutect2
- SPATS2 | c.1501G>T p.E501* | Nonsense Mutation (SNP) | VAF 45/339 reads (13%) | called by muse, mutect2, varscan2
- SPIRE1 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- STAT1 | c.1871G>T p.G624V | Missense Mutation (SNP) | VAF 36/430 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2
- STXBP4 | c.144T>A p.Y48* | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- STXBP5L | c.143A>G p.E48G | Missense Mutation (SNP) | VAF 46/365 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- SUDS3 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SUN5 | c.1069G>T p.V357L | Missense Mutation (SNP) | VAF 14/163 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- SYNE2 | c.5587G>C p.E1863Q | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- SYNJ1 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 20/118 reads (17%) | called by mutect2, varscan2
- SYNRG | c.2308G>T p.G770* | Nonsense Mutation (SNP) | VAF 65/401 reads (16%) | called by muse, mutect2, varscan2
- TAL1 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 41/334 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- TBX19 | c.962G>T p.G321V | Missense Mutation (SNP) | VAF 92/443 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCOF1 | c.2587G>C p.G863R (on ENST00000377797 / NM_001135243.1; = p.G786R on NM_000356.4) | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- TMEM199 | c.376-3del | Splice Region (DEL) | VAF 23/163 reads (14%) | called by mutect2, pindel, varscan2
- TMEM30A | c.433G>C p.G145R | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOX | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- TPPP2 | c.140C>A p.S47Y | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TRIM51 | c.290G>T p.R97I | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- TSPAN16 | c.627A>C p.K209N | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.401); called by muse, mutect2
- TTN | c.91881T>A p.N30627K (on ENST00000591111; = p.N23203K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | PolyPhen possibly damaging (0.52); called by muse, mutect2
- UGT2B4 | c.64A>G p.S22G | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- UNC80 | c.3297T>A p.D1099E | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- UPK1B | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP40 | c.3095G>T p.G1032V | Missense Mutation (SNP) | VAF 45/365 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- USP40 | c.3094G>T p.G1032C | Missense Mutation (SNP) | VAF 45/362 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- VEPH1 | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- VIRMA | c.2929C>A p.Q977K | Missense Mutation (SNP) | VAF 27/278 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- VOPP1 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR44 | c.2003T>C p.L668S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ZBED1 | c.634A>T p.T212S | Missense Mutation (SNP) | VAF 61/479 reads (13%) | SIFT tolerated (0.76); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZC3H14 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- ZFC3H1 | c.4225A>T p.R1409* | Nonsense Mutation (SNP) | VAF 27/254 reads (11%) | called by muse, mutect2
- ZKSCAN5 | c.2306G>T p.S769I | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNF160 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF213 | c.971A>T p.K324M | Missense Mutation (SNP) | VAF 59/375 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- ZNF236 | c.5068G>T p.V1690L | Missense Mutation (SNP) | VAF 82/583 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF253 | c.243del p.F81Lfs*16 | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- ZNF44 | c.1192G>C p.G398R (on ENST00000356109 / NM_001164276.2; = p.G350R on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ZNF785 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, mutect2
- ZNF785 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2
- ZYG11B | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 15/345 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- AATK | c.2700C>T p.P900= (on ENST00000326724 / NM_001080395.3; = p.P797= on NM_004920.2) | Silent (SNP) | VAF 40/229 reads (17%) | catalogued as rs373067135; called by muse, mutect2, varscan2
- ACSBG1 | c.1992G>A p.G664= | Silent (SNP) | VAF 40/460 reads (9%) | called by muse, mutect2
- ANKLE2 | c.381C>G p.V127= | Silent (SNP) | VAF 42/301 reads (14%) | called by muse, mutect2, varscan2
- ANKRD62 | c.1053C>T p.G351= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs1171180433; called by mutect2, varscan2
- C2CD5 | c.2904A>T p.A968= | Silent (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- CALHM5 | c.207G>C p.L69= | Silent (SNP) | VAF 39/217 reads (18%) | catalogued as rs145677955; called by muse, mutect2, varscan2
- CASZ1 | c.1518G>A p.Q506= | Silent (SNP) | VAF 25/172 reads (15%) | catalogued as rs749294063, COSV59735841; called by muse, mutect2, varscan2
- CBLIF | c.426G>T p.L142= | Silent (SNP) | VAF 69/611 reads (11%) | catalogued as COSV99950989; called by muse, mutect2, varscan2
- CD248 | c.2175C>T p.C725= | Silent (SNP) | VAF 32/385 reads (8%) | catalogued as rs144493283; called by muse, mutect2
- CDH13 | c.2121C>T p.L707= | Silent (SNP) | VAF 59/376 reads (16%) | called by muse, mutect2, varscan2
- CDH7 | c.618A>T p.P206= | Silent (SNP) | VAF 20/176 reads (11%) | called by muse, mutect2
- CLDN6 | c.198G>A p.V66= | Silent (SNP) | VAF 77/515 reads (15%) | called by muse, mutect2, varscan2
- CLDN7 | c.246C>G p.A82= | Silent (SNP) | VAF 45/246 reads (18%) | called by muse, mutect2, varscan2
- CTDP1 | c.1698C>T p.V566= | Silent (SNP) | VAF 32/252 reads (13%) | called by muse, varscan2
- CYP4A11 | c.681G>T p.L227= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as COSV100152547; called by muse, mutect2, varscan2
- DPY19L2 | c.1719T>A p.S573= | Silent (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- ENAM | c.3096C>G p.G1032= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV68537289; called by muse, mutect2
- FAM186A | c.999C>A p.S333= | Silent (SNP) | VAF 21/167 reads (13%) | called by muse, mutect2, varscan2
- FAT1 | c.10479G>T p.P3493= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as rs774680240, COSV71673909; called by muse, mutect2, varscan2
- FECH | c.861C>A p.V287= | Silent (SNP) | VAF 73/545 reads (13%) | called by muse, mutect2, varscan2
- FLG | c.7341A>G p.R2447= | Silent (SNP) | VAF 131/672 reads (19%) | called by muse, mutect2, varscan2
- FN1 | c.5265G>A p.R1755= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as rs151207381; called by muse, mutect2, varscan2
- FRY | c.8433A>T p.G2811= | Silent (SNP) | VAF 58/329 reads (18%) | called by muse, mutect2, varscan2
- GMNC | c.826C>T p.L276= | Silent (SNP) | VAF 45/415 reads (11%) | called by muse, mutect2, varscan2
- GPRIN1 | c.2571G>A p.A857= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs1200935275; called by muse, mutect2, varscan2
- GRIN2B | c.4446T>A p.S1482= | Silent (SNP) | VAF 14/135 reads (10%) | called by muse, mutect2, varscan2
- GRIN2C | c.729C>T p.A243= | Silent (SNP) | VAF 26/154 reads (17%) | catalogued as rs1263122816; called by muse, mutect2, varscan2
- HSPG2 | c.7812C>T p.N2604= | Silent (SNP) | VAF 53/441 reads (12%) | catalogued as rs564192590; called by muse, mutect2, varscan2
- INPP5D | c.768C>G p.A256= (on ENST00000445964 / NM_001017915.3; = p.A255= on NM_005541.5) | Silent (SNP) | VAF 36/285 reads (13%) | called by muse, mutect2, varscan2
- IP6K3 | c.309G>A p.A103= | Silent (SNP) | VAF 198/681 reads (29%) | catalogued as rs768197092, COSV99539641; called by muse, mutect2, varscan2
- IPO9 | c.450G>T p.L150= | Silent (SNP) | VAF 98/521 reads (19%) | called by muse, mutect2, varscan2
- ITIH5 | c.2316G>T p.V772= | Silent (SNP) | VAF 27/155 reads (17%) | called by muse, mutect2, varscan2
- KCNN3 | c.2049C>A p.A683= (on ENST00000618040 / NM_001204087.1; = p.A668= on NM_002249.6) | Silent (SNP) | VAF 58/375 reads (15%) | called by muse, mutect2, varscan2
- KIF6 | c.390G>A p.Q130= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV54670628; called by muse, mutect2
- KLHL38 | c.801C>A p.V267= | Silent (SNP) | VAF 58/539 reads (11%) | called by muse, mutect2, varscan2
- LCMT2 | c.189G>C p.V63= | Silent (SNP) | VAF 27/161 reads (17%) | called by muse, mutect2, varscan2
- LPCAT2 | c.498A>G p.R166= | Silent (SNP) | VAF 36/224 reads (16%) | called by muse, mutect2
- LRP1B | c.8329C>A p.R2777= | Silent (SNP) | VAF 22/207 reads (11%) | catalogued as COSV67198045, COSV67229562; called by muse, mutect2, varscan2
- LTB4R2 | c.807C>T p.A269= (on ENST00000528054; = p.A238= on NM_019839.5) | Silent (SNP) | VAF 91/572 reads (16%) | catalogued as rs1373183810; called by muse, mutect2, varscan2
- MAGI1 | c.3645C>T p.S1215= (on ENST00000402939 / NM_001033057.2; = p.A1273V on NM_015520.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV58333846; called by muse, mutect2
- MAP1S | c.2883C>T p.H961= | Silent (SNP) | VAF 20/166 reads (12%) | called by muse, mutect2
- MASTL | c.90C>G p.P30= | Silent (SNP) | VAF 58/490 reads (12%) | catalogued as rs1317044734, COSV100464141; called by muse, mutect2, varscan2
- MKRN2 | c.1250A>G p.*417= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as rs763002762; called by muse, mutect2, varscan2
- MYH14 | c.5466T>C p.D1822= | Silent (SNP) | VAF 45/389 reads (12%) | called by muse, mutect2, varscan2
- MYH2 | c.822T>C p.S274= | Silent (SNP) | VAF 26/218 reads (12%) | called by muse, mutect2, varscan2
- MYO18B | c.3435C>A p.G1145= | Silent (SNP) | VAF 46/273 reads (17%) | called by muse, mutect2, varscan2
- MYPN | c.594T>C p.S198= | Silent (SNP) | VAF 65/266 reads (24%) | called by muse, mutect2, varscan2
- NDUFB1 | c.90G>A p.K30= | Silent (SNP) | VAF 89/366 reads (24%) | called by muse, mutect2, varscan2
- NLGN1 | c.363C>T p.I121= | Silent (SNP) | VAF 33/306 reads (11%) | catalogued as COSV64340719; called by muse, mutect2, varscan2
- NLRP3 | c.1713G>A p.L571= | Silent (SNP) | VAF 161/896 reads (18%) | catalogued as CM082978; called by muse, mutect2, varscan2
- NPAS2 | c.2307C>G p.T769= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1319840061; called by muse, mutect2
- NR4A3 | c.651C>T p.A217= | Silent (SNP) | VAF 23/130 reads (18%) | catalogued as rs900080632; called by muse, mutect2, varscan2
- OR6K6 | c.606C>A p.I202= (on ENST00000368144; = p.I178= on NM_001005184.1) | Silent (SNP) | VAF 18/298 reads (6%) | called by muse, mutect2
- PIGQ | c.606G>C p.A202= | Silent (SNP) | VAF 29/203 reads (14%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.801C>G p.A267= | Silent (SNP) | VAF 47/337 reads (14%) | called by muse, mutect2, varscan2
- PTCD1 | c.1137G>A p.L379= | Silent (SNP) | VAF 60/417 reads (14%) | called by muse, mutect2, varscan2
- PTPN22 | c.2424A>G p.*808= (on ENST00000359785 / NM_001193431.2; = p.*753= on NM_012411.5) | Silent (SNP) | VAF 24/166 reads (14%) | called by muse, mutect2, varscan2
- PTPRJ | c.3282C>T p.Y1094= | Silent (SNP) | VAF 26/166 reads (16%) | called by muse, mutect2, varscan2
- PTRH1 | c.489C>T p.I163= | Silent (SNP) | VAF 33/198 reads (17%) | catalogued as rs557298488; called by muse, mutect2, varscan2
- RANBP17 | c.3036T>C p.N1012= | Silent (SNP) | VAF 40/229 reads (17%) | called by muse, mutect2, varscan2
- RIMS1 | c.966G>T p.G322= | Silent (SNP) | VAF 68/446 reads (15%) | called by muse, mutect2, varscan2
- RNASE13 | c.273C>T p.S91= | Silent (SNP) | VAF 17/104 reads (16%) | called by muse, mutect2, varscan2
- SELENOO | c.1839C>T p.F613= | Silent (SNP) | VAF 24/184 reads (13%) | catalogued as COSV50538373; called by muse, mutect2, varscan2
- SERPING1 | c.1122C>G p.L374= | Silent (SNP) | VAF 68/562 reads (12%) | catalogued as COSV53543027; called by muse, varscan2
- SERPINI2 | c.1038T>C p.A346= | Silent (SNP) | VAF 69/463 reads (15%) | called by muse, mutect2, varscan2
- SI | c.4311C>T p.C1437= | Silent (SNP) | VAF 21/174 reads (12%) | called by muse, mutect2, varscan2
- SLC16A2 | c.1230C>T p.F410= | Silent (SNP) | VAF 32/125 reads (26%) | catalogued as rs776772853, COSV99330992; called by muse, mutect2, varscan2
- SLC6A3 | c.1381C>T p.L461= | Silent (SNP) | VAF 65/750 reads (9%) | called by muse, mutect2
- SLITRK3 | c.1278T>A p.S426= | Silent (SNP) | VAF 22/184 reads (12%) | called by muse, varscan2
- TBL2 | c.258G>C p.L86= | Silent (SNP) | VAF 26/163 reads (16%) | called by muse, mutect2, varscan2
- TBL3 | c.1515C>G p.L505= | Silent (SNP) | VAF 77/534 reads (14%) | called by muse, mutect2, varscan2
- TGFB2 | c.222C>T p.T74= | Silent (SNP) | VAF 17/334 reads (5%) | called by muse, mutect2
- TMEM161B | c.1419A>T p.T473= | Silent (SNP) | VAF 20/142 reads (14%) | called by muse, mutect2
- TMEM232 | c.60T>C p.P20= | Silent (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- TOMM6 | c.60A>T p.I20= | Silent (SNP) | VAF 20/318 reads (6%) | called by muse, mutect2
- TOP2A | c.3603G>A p.K1201= | Silent (SNP) | VAF 32/278 reads (12%) | catalogued as rs756146500; called by muse, mutect2, varscan2
- TPPP2 | c.141C>A p.S47= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as COSV100069333; called by muse, mutect2, varscan2
- TRPM1 | c.3417G>T p.R1139= | Silent (SNP) | VAF 42/329 reads (13%) | catalogued as COSV56640289; called by muse, mutect2, varscan2
- UBE2E1 | c.276G>A p.E92= | Silent (SNP) | VAF 17/197 reads (9%) | called by muse, mutect2
- VPS13D | c.4341T>A p.S1447= | Silent (SNP) | VAF 35/271 reads (13%) | called by muse, mutect2, varscan2
- WNT3 | c.144C>T p.I48= | Silent (SNP) | VAF 42/363 reads (12%) | catalogued as rs1190336114, COSV99843500; called by muse, mutect2, varscan2
- ZBTB43 | c.321A>G p.A107= | Silent (SNP) | VAF 32/178 reads (18%) | called by muse, mutect2, varscan2
- ZBTB46 | c.279G>C p.A93= | Silent (SNP) | VAF 41/247 reads (17%) | catalogued as COSV55514571; called by muse, mutect2, varscan2
- ABAT | c.1382-30C>A | Intron (SNP) | VAF 62/564 reads (11%) | catalogued as rs200203278; called by muse, varscan2
- AC004837.1 | n.21G>C | RNA (SNP) | VAF 36/396 reads (9%) | called by muse, mutect2
- AC005400.1 | n.87-20750G>T | Intron (SNP) | VAF 62/244 reads (25%) | called by muse, mutect2, varscan2
- AC016582.1 | chr19:37824650 C>G | 3'Flank (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- AC099548.2 | n.1471G>T | RNA (SNP) | VAF 66/782 reads (8%) | called by muse, mutect2
- ACSM2B | c.597-239A>G | Intron (SNP) | VAF 28/172 reads (16%) | called by muse, mutect2, varscan2
- ADGRE2 | chr19:14731227 A>T | 3'Flank (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- BROX | c.-205C>T | 5'UTR (SNP) | VAF 32/235 reads (14%) | catalogued as rs957214749; called by muse, mutect2, varscan2
- CA2 | c.-45C>A | 5'UTR (SNP) | VAF 92/710 reads (13%) | called by muse, varscan2
- CHID1 | chr11:914549 G>C | 5'Flank (SNP) | VAF 33/252 reads (13%) | called by muse, mutect2, varscan2
- COL1A2 | c.-44A>G | 5'UTR (SNP) | VAF 52/255 reads (20%) | catalogued as COSV99801129; called by muse, mutect2, varscan2
- CTTN | c.*515G>C | 3'UTR (SNP) | VAF 337/812 reads (42%) | called by muse, mutect2, varscan2
- DAB1 | c.597+47C>G | Intron (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- DDHD1 | chr14:53152961 G>A | 5'Flank (SNP) | VAF 159/521 reads (31%) | catalogued as rs765127742; called by muse, mutect2, varscan2
- DPAGT1 | c.1006-48T>G | Intron (SNP) | VAF 47/300 reads (16%) | called by muse, mutect2, varscan2
- EEF1AKMT3 | c.289+1601C>T | Intron (SNP) | VAF 25/186 reads (13%) | catalogued as rs149061035; called by muse, mutect2, varscan2
- EPB41L2 | c.2044-230C>A | Intron (SNP) | VAF 51/299 reads (17%) | called by muse, mutect2, varscan2
- ERGIC3 | chr20:35561883 G>C | 3'Flank (SNP) | VAF 5/82 reads (6%) | catalogued as rs1368760616; called by muse, mutect2
- FAM136A | c.87+374G>T | Intron (SNP) | VAF 61/487 reads (13%) | called by muse, mutect2, varscan2
- HAND1 | c.-24del | 5'UTR (DEL) | VAF 33/225 reads (15%) | catalogued as COSV50562782; called by mutect2, pindel, varscan2
- IGFN1 | c.1241+2851A>G | Intron (SNP) | VAF 48/267 reads (18%) | called by muse, mutect2, varscan2
- LARS1 | c.-27G>T | 5'UTR (SNP) | VAF 38/297 reads (13%) | called by muse, mutect2, varscan2
- LHX1 | chr17:36937186 G>T | 5'Flank (SNP) | VAF 34/326 reads (10%) | called by muse, mutect2
- MAP4K4 | chr2:101893036 G>A | 3'Flank (SNP) | VAF 29/233 reads (12%) | called by muse, mutect2, varscan2
- MATR3 | chr5:139274088 C>G | 5'Flank (SNP) | VAF 24/169 reads (14%) | catalogued as rs1188098296; called by muse, mutect2, varscan2
- MED13L | c.2345-47G>A | Intron (SNP) | VAF 24/344 reads (7%) | catalogued as rs919467816; called by muse, mutect2
- MIR96 | n.43G>T | RNA (SNP) | VAF 41/248 reads (17%) | catalogued as rs370173345; called by muse, mutect2, varscan2
- MTCL1 | c.2968-3117C>T | Intron (SNP) | VAF 26/161 reads (16%) | called by muse, mutect2, varscan2
- MYOCD | c.2059-1598G>C | Intron (SNP) | VAF 32/252 reads (13%) | called by muse, mutect2, varscan2
- NBPF22P | n.1325C>A | RNA (SNP) | VAF 58/525 reads (11%) | called by muse, mutect2, varscan2
- NME9 | c.-21C>A | 5'UTR (SNP) | VAF 28/169 reads (17%) | called by muse, mutect2, varscan2
- OACYLP | n.1375T>G | RNA (SNP) | VAF 24/203 reads (12%) | called by muse, mutect2, varscan2
- PACRG | c.613+102292T>C | Intron (SNP) | VAF 22/192 reads (11%) | called by muse, mutect2, varscan2
- PARVG | c.144+710C>A | Intron (SNP) | VAF 34/273 reads (12%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67899G>T | Intron (SNP) | VAF 31/254 reads (12%) | called by muse, mutect2, varscan2
- PENK | c.138+127G>C | Intron (SNP) | VAF 12/77 reads (16%) | catalogued as COSV100152168; called by muse, mutect2, varscan2
- PES1 | c.-1G>A | 5'UTR (SNP) | VAF 24/225 reads (11%) | called by muse, mutect2, varscan2
- PPP6R3 | c.2451-376A>G | Intron (SNP) | VAF 56/325 reads (17%) | called by muse, mutect2, varscan2
- RIC8B | c.742-2307G>C | Intron (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2, varscan2
- RNGTT | chr6:88966057 C>G | 5'Flank (SNP) | VAF 27/236 reads (11%) | called by muse, mutect2, varscan2
- SERPINA13P | n.936A>G | RNA (SNP) | VAF 50/524 reads (10%) | called by muse, mutect2
- SERPING1 | c.1030-9A>C | Intron (SNP) | VAF 46/391 reads (12%) | called by muse, varscan2
- SETD9 | c.98+591G>A | Intron (SNP) | VAF 40/309 reads (13%) | catalogued as rs1339965394; called by muse, mutect2, varscan2
- SLAMF7 | c.649+15C>A | Intron (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2, varscan2
- SOX8 | chr16:976845 C>G | 5'Flank (SNP) | VAF 89/611 reads (15%) | called by muse, mutect2, varscan2
- SPANXN4 | chrX:143034544 C>T | 3'Flank (SNP) | VAF 14/29 reads (48%) | called by muse, varscan2
- SPATA31D5P | n.1123G>C | RNA (SNP) | VAF 55/258 reads (21%) | catalogued as rs1010223706; called by muse, mutect2, varscan2
- STAT5B | c.-5A>C | 5'UTR (SNP) | VAF 33/258 reads (13%) | called by muse, mutect2, varscan2
- TAC4 | c.123+798C>A | Intron (SNP) | VAF 37/313 reads (12%) | called by muse, mutect2, varscan2
- TFAP2E | c.-6C>G | 5'UTR (SNP) | VAF 20/302 reads (7%) | catalogued as rs200464156; called by muse, mutect2
- TTN | c.10360+3849A>T | Intron (SNP) | VAF 23/142 reads (16%) | called by muse, mutect2, varscan2
- UBE2H | c.-16A>T | 5'UTR (SNP) | VAF 22/148 reads (15%) | called by muse, mutect2, varscan2
- UQCRB | c.*2718T>C | 3'UTR (SNP) | VAF 18/166 reads (11%) | called by muse, mutect2
- VWA3A | c.2840-546G>T | Intron (SNP) | VAF 28/315 reads (9%) | called by muse, mutect2
- ZFP82 | c.230-17T>G | Intron (SNP) | VAF 7/53 reads (13%) | called by muse, mutect2, varscan2
- ZNF48 | c.-273C>T | 5'UTR (SNP) | VAF 46/293 reads (16%) | catalogued as rs1474213525; called by muse, mutect2, varscan2
- ZNF540 | c.-21A>T | 5'UTR (SNP) | VAF 32/148 reads (22%) | called by muse, mutect2, varscan2
